Somatic mutation profile of tumor specimen 0DI7VA from CCDI case PBBUTB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,830 days).
Specimen 0DI7VA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19d7c35c-0013-4b69-83d7-2affb8f2f5b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI7VF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/baa8abc1-909e-4852-97e9-0c65103b0a9d

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALT1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 188/597 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755225132, COSV65707689, COSV65708259; called by muse, mutect2, varscan2
- MBIP | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 28/601 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs752112157, COSV59253534; called by muse, mutect2
- NCAM2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 262/543 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs201907310, COSV53103643; called by muse, mutect2, varscan2
- POLRMT | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 143/441 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.556); catalogued as rs1352517780, COSV52114793; called by muse, mutect2, varscan2
- TAF1 | c.2500C>T p.R834C (on ENST00000373790 / NM_138923.4; = p.R855C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 234/544 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52109994; called by muse, mutect2, varscan2
- TMEM200A | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 197/932 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs149308469, COSV51656363; called by muse, mutect2, varscan2
- ADGRG4 | c.5224T>A p.S1742T | Missense Mutation (SNP) | VAF 232/727 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- C1orf115 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 386/651 reads (59%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- MAP3K12 | c.2238G>A p.Q746= | Silent (SNP) | VAF 153/493 reads (31%) | called by muse, mutect2, varscan2
- SALL3 | c.3246G>A p.A1082= | Silent (SNP) | VAF 147/471 reads (31%) | catalogued as rs1167761179, COSV73305767, COSV73306527; called by muse, mutect2, varscan2
- TAZ | c.519C>T p.D173= | Silent (SNP) | VAF 188/586 reads (32%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40525364 C>A | 5'Flank (SNP) | VAF 24/312 reads (8%) | catalogued as rs1361669830; called by muse, mutect2
